Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A1PV, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A1PV-01A (Primary Tumor).

Project #
TSS:

ICD-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS 44.9 3/12/11 *lw*

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format
1		5		Caucasian (White)	Melanoma		Female		Skin	Primary	Tumor	Tissue	Frozen
		5		Caucasian (White)	Melanoma		Female		Blood	n/a	normal	Blood	Frozen

Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation	Cellular Tumor %
cryomold	1	200	mg	Surgery	Melanoma	n/a	4b	0	0	no	no	no	90
tube	1	4	ml	Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no	n/a

Source: NCI Genomic Data Commons file 5792242c-2d95-4eb0-bc65-57ed800f9e8d (TCGA-BF-A1PV.8D2DF32C-6921-47FF-AB4A-6C1C931E130D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).